Somatic mutation profile of cancer-model specimen HCM-CSHL-0382-C19-85A (3D Organoid; aliquot HCM-CSHL-0382-C19-85A-01D-A78T-36), derived from the primary tumor of HCMI case HCM-CSHL-0382-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 68.0 years (24,847 days).
Specimen HCM-CSHL-0382-C19-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5097e316-324c-4557-8694-15a6dd369030.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0382-C19-10A (Blood Derived Normal), aliquot HCM-CSHL-0382-C19-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2aa8c341-ae21-4e3b-b5c3-57fae797017c

The open-access MAF lists 206 somatic variants for this specimen: 134 protein-altering or splice-affecting, 51 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 51, Intron 10, Nonsense Mutation 9, 3'UTR 4, Frame Shift Del 4, Splice Region 4, RNA 3, Frame Shift Ins 3, 5'UTR 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1263G>A p.W421* | Nonsense Mutation (SNP) | VAF 62/149 reads (42%) | catalogued as rs1554080106, CM083583, CX1110728, COSV57320574, COSV57364239; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4132C>T p.Q1378* | Nonsense Mutation (SNP) | VAF 84/162 reads (52%) | hotspot (GDC flag); catalogued as rs121913329, CD1110399, CM095537, COSV57322261; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- EP300 | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 41/235 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519889, COSV54325045, COSV54326888, COSV54344606; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3575G>A p.R1192H | Missense Mutation (SNP) | VAF 256/773 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60785906, COSV60794673; called by muse, mutect2, varscan2
- TP53 | c.338T>G p.F113C | Missense Mutation (SNP) | VAF 164/164 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1567555667, COSV52680942, COSV52985275; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRB3 | c.1484C>T p.T495M | Missense Mutation (SNP) | VAF 96/183 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs113677156, COSV65405340; called by muse, mutect2, varscan2
- ATP7B | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as rs1425712013; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4186G>T p.D1396Y | Missense Mutation (SNP) | VAF 108/591 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63244314; called by muse, mutect2, varscan2
- C2orf81 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV99292489; called by muse, mutect2, varscan2
- CDR2 | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs145347510; called by muse, mutect2, varscan2
- CHRNA4 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.146); catalogued as rs150336658; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CHST15 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 169/307 reads (55%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1281580042, COSV99068214; called by muse, mutect2, varscan2
- CHTF18 | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 112/300 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs927638441; called by muse, mutect2, varscan2
- COL15A1 | c.4027C>T p.R1343* | Nonsense Mutation (SNP) | VAF 96/198 reads (48%) | catalogued as rs1450959518, COSV66640905; called by muse, mutect2, varscan2
- DCN | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 21/143 reads (15%) | catalogued as rs866641462; called by muse, mutect2, varscan2
- DHX37 | c.2635G>A p.G879R | Missense Mutation (SNP) | VAF 112/451 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148208268; called by muse, mutect2, varscan2
- DLG2 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs146095353, COSV104381829; called by muse, mutect2, varscan2
- DUSP11 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 166/577 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs1307552596; called by muse, mutect2, varscan2
- FARP2 | c.906T>A p.S302R | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV50870080; called by muse, mutect2
- FLG | c.9593T>G p.V3198G | Missense Mutation (SNP) | VAF 212/695 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs143183339; called by muse, mutect2, varscan2
- FNBP4 | c.2908C>T p.R970W | Missense Mutation (SNP) | VAF 79/267 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs773342165; called by muse, mutect2, varscan2
- GPHN | c.1690C>A p.R564S (on ENST00000315266 / NM_001377519.1; = p.R597S on NM_020806.5) | Missense Mutation (SNP) | VAF 182/353 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV104400759; called by muse, mutect2, varscan2
- GPR37 | c.1364C>T p.T455M | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.769); catalogued as rs774806947, COSV58259643; called by muse, mutect2, varscan2
- GPRIN1 | c.2240G>A p.R747H | Missense Mutation (SNP) | VAF 79/238 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1445549801, COSV56134983; called by muse, mutect2, varscan2
- HYAL3 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs377396269; called by muse, mutect2, varscan2
- ITIH1 | c.2548G>A p.D850N | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as rs774566520; called by muse, mutect2, varscan2
- ITIH3 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.069); catalogued as rs765314854, COSV69649389; called by muse, mutect2, varscan2
- LCT | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 87/132 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1017501359, COSV51555251, COSV99928905; called by muse, mutect2, varscan2
- LRP8 | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 222/468 reads (47%) | SIFT tolerated (0.92); PolyPhen benign (0.313); catalogued as rs1216741308; called by muse, mutect2, varscan2
- LUZP2 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV61199830; called by muse, mutect2
- MFSD9 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as rs372925047, COSV51492718; called by muse, mutect2
- MOGAT3 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 122/359 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as rs139340331, COSV56175477; called by muse, mutect2, varscan2
- MYBPC1 | c.1715G>A p.R572Q (on ENST00000550270 / NM_206820.2; = p.R597Q on NM_002465.4) | Missense Mutation (SNP) | VAF 169/476 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs149018411, COSV62252673; called by muse, mutect2, varscan2
- NCKAP1L | c.2959A>G p.T987A | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs757398054; called by muse, mutect2, varscan2
- OR8K5 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756900844, COSV57889897, COSV57889909; called by muse, mutect2, varscan2
- PCDHA7 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 316/491 reads (64%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as rs782575776, COSV100971806, COSV65346027; called by muse, mutect2, varscan2
- PCDHGB5 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 254/858 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs756009874, COSV53966911; called by muse, mutect2, varscan2
- PLN | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 147/326 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.488); catalogued as rs761056344, CM152289, COSV100682504, COSV62645794; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPDPFL | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as rs1327256996, COSV57460875, COSV57460969; called by muse, mutect2, varscan2
- RAB38 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 75/227 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760114172, COSV54712089; called by muse, mutect2, varscan2
- RAD21 | c.1757G>A p.R586Q | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.979); catalogued as rs780692465, COSV52061251, COSV52061293; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAPGEF4 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV51389637; called by muse, mutect2, varscan2
- RING1 | c.767C>A p.P256Q | Missense Mutation (SNP) | VAF 70/120 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.212); catalogued as rs1288256354; called by muse, mutect2, varscan2
- ROBO2 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 72/128 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778332221, COSV59906905; called by muse, mutect2, varscan2
- SEC16A | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 72/136 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs1445008267; called by muse, mutect2, varscan2
- SIM1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV53496896; called by muse, mutect2, varscan2
- SLC16A14 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 29/127 reads (23%) | catalogued as COSV54621965; called by muse, mutect2, varscan2
- SMPDL3A | c.111A>G p.I37M | Missense Mutation (SNP) | VAF 218/409 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs1234418516; called by muse, mutect2, varscan2
- SPATA12 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 50/308 reads (16%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1219057174; called by muse, mutect2, varscan2
- SPTBN4 | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 106/309 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.216); catalogued as rs763945874; called by muse, mutect2, varscan2
- SRXN1 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 31/732 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs144940742; called by muse, mutect2
- SYNE1 | c.19695C>T p.D6565= (on ENST00000367255 / NM_182961.4; = p.D6494= on NM_033071.3) | Splice Region (SNP) | VAF 81/457 reads (18%) | catalogued as rs748526264; called by muse, mutect2, varscan2
- SYTL4 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 146/522 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201221018, COSV52170730; called by muse, varscan2
- TBC1D17 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs117240064; called by muse, mutect2, varscan2
- TBX20 | c.23A>G p.K8R | Missense Mutation (SNP) | VAF 97/536 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as rs760680589; called by muse, mutect2
- TECRL | c.333C>T p.G111= | Splice Region (SNP) | VAF 49/82 reads (60%) | catalogued as rs535849187, COSV67085280; called by muse, mutect2, varscan2
- TECTA | c.3283C>T p.R1095C | Missense Mutation (SNP) | VAF 232/360 reads (64%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as rs931887540; called by muse, mutect2, varscan2
- TNXB | c.5093C>T p.P1698L (on ENST00000647633; = p.P1451L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 180/314 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771493330; called by muse, mutect2, varscan2
- TOR2A | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 124/250 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1239249032; called by muse, mutect2, varscan2
- TRIB3 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 141/720 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs200611082, COSV53933040; called by muse, mutect2, varscan2
- TRIM58 | c.1087T>G p.C363G | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV63569699; called by muse, mutect2, varscan2
- TTLL7 | c.1366C>T p.R456* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as rs868019143; called by muse, mutect2, varscan2
- ZNF470 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 67/203 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV57967824; called by muse, mutect2, varscan2
- ZNF577 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 55/379 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs768421805, COSV56814925; called by muse, mutect2, varscan2
- ZNF583 | c.864_865del p.R288Sfs*11 | Frame Shift Del (DEL) | VAF 58/266 reads (22%) | catalogued as rs759925007; called by pindel, varscan2
- ZNF791 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 48/71 reads (68%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as rs765211548; called by muse, mutect2, varscan2
- ZNF835 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 151/593 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1309824359, COSV73379606, COSV73379622; called by muse, mutect2, varscan2
- ABCA13 | c.10768A>G p.K3590E | Missense Mutation (SNP) | VAF 22/314 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AKR1C2 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ANKRD30B | c.4042_4043insC p.N1348Tfs*2 | Frame Shift Ins (INS) | VAF 6/12 reads (50%) | called by mutect2, pindel, varscan2
- APBA3 | c.598del p.Y200Tfs*64 | Frame Shift Del (DEL) | VAF 40/160 reads (25%) | called by mutect2, pindel, varscan2
- ARHGAP25 | c.1429G>T p.A477S (on ENST00000409202 / NM_001007231.3; = p.A469S on NM_014882.3) | Missense Mutation (SNP) | VAF 39/401 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARRDC5 | c.555G>T p.Q185H (on ENST00000381781; = p.Q171H on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/233 reads (30%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ATP2B2 | c.1942_1944del p.K648del (on ENST00000352432; = p.K614del on NM_001683.5) | In Frame Del (DEL) | VAF 81/218 reads (37%) | called by pindel, varscan2
- BLZF1 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 38/322 reads (12%) | called by muse, mutect2, varscan2
- C3orf22 | c.59A>T p.Q20L | Missense Mutation (SNP) | VAF 79/203 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- CCDC15 | c.1980C>A p.D660E | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CNDP2 | c.903G>T p.K301N | Missense Mutation (SNP) | VAF 40/40 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- CNTN1 | c.2605G>T p.E869* | Nonsense Mutation (SNP) | VAF 74/200 reads (37%) | called by muse, mutect2, varscan2
- COL9A1 | c.1735C>A p.P579T | Missense Mutation (SNP) | VAF 88/180 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- CYP2S1 | c.801C>G p.D267E | Missense Mutation (SNP) | VAF 85/226 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DDI1 | c.215T>A p.V72E | Missense Mutation (SNP) | VAF 50/511 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- DDI2 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 72/142 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DHRS12 | c.223G>T p.A75S | Missense Mutation (SNP) | VAF 63/520 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DNAH5 | c.13149G>A p.M4383I | Missense Mutation (SNP) | VAF 196/413 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- DPYS | c.1235+1G>T p.X412_splice | Splice Site (SNP) | VAF 94/334 reads (28%) | called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2026del p.Q676Rfs*3 | Frame Shift Del (DEL) | VAF 35/87 reads (40%) | called by mutect2, pindel, varscan2
- EPHA7 | c.932A>C p.E311A | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- FARP1 | c.2347A>C p.N783H | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FRMD4A | c.2786G>A p.R929H | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- GABRA1 | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 96/286 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- GAD2 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.114); called by muse, mutect2
- GLI1 | c.627T>C p.D209= | Splice Region (SNP) | VAF 113/175 reads (65%) | called by muse, mutect2, varscan2
- GRID2 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 87/211 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- GTSF1L | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 47/294 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- INKA1 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, varscan2
- INPP4B | c.100A>G p.K34E | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- IRS1 | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 233/401 reads (58%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- JAK2 | c.228T>C p.G76= | Splice Region (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- KIAA1217 | c.3457C>T p.H1153Y | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- LRP1B | c.7211G>A p.G2404E | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.634); called by muse, mutect2
- MAP4K4 | c.3397C>A p.L1133I (on ENST00000347699 / NM_001242559.2; = p.L1059I on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- MED14 | c.2944G>A p.D982N | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NCAM2 | c.806G>C p.R269T | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- NID2 | c.2372G>T p.G791V | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLGN4X | c.1567G>C p.V523L | Missense Mutation (SNP) | VAF 186/628 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- NOMO1 | c.1081G>T p.A361S | Missense Mutation (SNP) | VAF 40/326 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NT5DC3 | c.1091T>C p.I364T | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- OASL | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 152/498 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- OR1D5 | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 26/709 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OSBPL6 | c.365C>A p.P122Q | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OVCH1 | c.2894G>T p.S965I | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- PARG | c.1954G>T p.E652* | Nonsense Mutation (SNP) | VAF 62/136 reads (46%) | called by muse, mutect2, varscan2
- PIGG | c.2444C>T p.P815L (on ENST00000453061 / NM_001127178.3; = p.P807L on NM_017733.4) | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- POLR1A | c.1618C>T p.R540W | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- QTRT1 | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 82/266 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RESF1 | c.3897del p.H1300Tfs*3 | Frame Shift Del (DEL) | VAF 31/92 reads (34%) | called by mutect2, pindel, varscan2
- ROBO1 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPL36 | c.111dup p.K38Qfs*79 | Frame Shift Ins (INS) | VAF 94/386 reads (24%) | called by mutect2, pindel, varscan2
- RYR3 | c.11948A>T p.H3983L (on ENST00000389232; = p.H3984L on NM_001036.6) | Missense Mutation (SNP) | VAF 52/209 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- SEC63 | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- SLCO5A1 | c.1426G>A p.V476I | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SND1 | c.1876G>A p.A626T | Missense Mutation (SNP) | VAF 110/404 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- SPACA7 | c.283A>G p.N95D | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- SPATA31E1 | c.2680T>G p.F894V | Missense Mutation (SNP) | VAF 115/252 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SUPT20HL1 | c.425T>A p.V142D | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM94 | c.1001G>T p.W334L | Missense Mutation (SNP) | VAF 89/267 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TNR | c.2624T>C p.V875A | Missense Mutation (SNP) | VAF 101/190 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- TTN | c.69175C>A p.P23059T (on ENST00000591111; = p.P15635T on NM_003319.4) | Missense Mutation (SNP) | VAF 84/136 reads (62%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VKORC1L1 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 120/377 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); called by muse, varscan2
- VPS13C | c.3751G>T p.V1251F (on ENST00000644861 / NM_020821.3; = p.V1208F on NM_017684.5) | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZIK1 | c.738dup p.A247Sfs*25 | Frame Shift Ins (INS) | VAF 71/276 reads (26%) | called by mutect2, pindel, varscan2
- ZNF655 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF99 | c.943T>C p.C315R | Missense Mutation (SNP) | VAF 130/444 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA13 | c.10902C>A p.I3634= | Silent (SNP) | VAF 75/513 reads (15%) | catalogued as COSV71293577; called by muse, mutect2, varscan2
- ADAR | c.3558G>A p.K1186= | Silent (SNP) | VAF 90/754 reads (12%) | called by muse, mutect2, varscan2
- ALDH1L2 | c.2226C>T p.D742= | Silent (SNP) | VAF 57/198 reads (29%) | catalogued as rs781613297; called by muse, mutect2, varscan2
- ARAP1 | c.1329C>T p.R443= (on ENST00000393609 / NM_001040118.2; = p.R198= on NM_015242.4) | Silent (SNP) | VAF 169/565 reads (30%) | catalogued as rs975746779, COSV61993548; called by muse, mutect2, varscan2
- B3GALNT2 | c.666A>T p.T222= | Silent (SNP) | VAF 115/228 reads (50%) | called by muse, mutect2, varscan2
- CACNB2 | c.909G>T p.A303= (on ENST00000324631 / NM_201596.3; = p.A248= on NM_000724.4) | Silent (SNP) | VAF 84/204 reads (41%) | called by muse, mutect2, varscan2
- CFAP74 | c.3492C>T p.H1164= | Silent (SNP) | VAF 55/99 reads (56%) | catalogued as rs1330941752; called by muse, mutect2, varscan2
- CLPP | c.480C>T p.A160= | Silent (SNP) | VAF 49/461 reads (11%) | catalogued as rs751283235; called by muse, mutect2, varscan2
- CNTN6 | c.1134G>T p.V378= | Silent (SNP) | VAF 37/98 reads (38%) | called by muse, mutect2, varscan2
- DLGAP4 | c.2931C>T p.S977= (on ENST00000339266 / NM_001365621.1; = p.S974= on NM_014902.6) | Silent (SNP) | VAF 124/496 reads (25%) | catalogued as rs150199875; called by muse, mutect2, varscan2
- DPP7 | c.279G>A p.E93= | Silent (SNP) | VAF 155/307 reads (50%) | catalogued as rs1361750987; called by muse, varscan2
- EFCAB8 | c.1995C>T p.T665= | Silent (SNP) | VAF 116/591 reads (20%) | catalogued as rs539746872; called by muse, mutect2, varscan2
- EFNA5 | c.525C>T p.F175= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs750182897, COSV60948312; called by muse, mutect2, varscan2
- EPHA6 | c.924G>A p.L308= | Silent (SNP) | VAF 63/105 reads (60%) | catalogued as COSV101064308, COSV67556607; called by muse, mutect2, varscan2
- EPPK1 | c.2377C>T p.L793= | Silent (SNP) | VAF 85/246 reads (35%) | catalogued as COSV73261057; called by muse, mutect2, varscan2
- ERAP2 | c.2322C>T p.F774= | Silent (SNP) | VAF 73/149 reads (49%) | called by muse, mutect2, varscan2
- FANCG | c.390C>T p.C130= | Silent (SNP) | VAF 247/540 reads (46%) | catalogued as rs1489760268; called by muse, mutect2, varscan2
- GRHPR | c.525C>T p.F175= | Silent (SNP) | VAF 219/445 reads (49%) | catalogued as rs749885934, COSV58945798; called by muse, mutect2, varscan2
- IGHV3-72 | c.111G>T p.L37= | Silent (SNP) | VAF 159/357 reads (45%) | called by muse, mutect2, varscan2
- IGKV3D-20 | c.87C>T p.A29= | Silent (SNP) | VAF 181/645 reads (28%) | called by muse, mutect2, varscan2
- IRAK4 | c.1014G>A p.K338= | Silent (SNP) | VAF 21/88 reads (24%) | called by muse, mutect2, varscan2
- KMT2D | c.1323G>T p.L441= | Silent (SNP) | VAF 10/24 reads (42%) | called by muse, varscan2
- KRT1 | c.1920C>A p.S640= | Silent (SNP) | VAF 171/474 reads (36%) | catalogued as COSV52868110; called by muse, mutect2, varscan2
- LRRC23 | c.408G>T p.L136= | Silent (SNP) | VAF 159/486 reads (33%) | called by muse, mutect2, varscan2
- MAGEB6B | c.918G>A p.E306= | Silent (SNP) | VAF 107/343 reads (31%) | called by muse, mutect2, varscan2
- MAP2K2 | c.903C>T p.P301= | Silent (SNP) | VAF 120/344 reads (35%) | catalogued as rs560316877; ClinVar: likely benign; called by muse, mutect2, varscan2
- MTUS2 | c.1683C>T p.F561= | Silent (SNP) | VAF 46/190 reads (24%) | catalogued as rs376749747; called by muse, mutect2, varscan2
- NIBAN3 | c.1743G>A p.L581= | Silent (SNP) | VAF 69/264 reads (26%) | called by muse, mutect2, varscan2
- NR2C1 | c.747A>G p.V249= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV58009082; called by muse, mutect2, varscan2
- OSMR | c.1962T>G p.P654= | Silent (SNP) | VAF 118/275 reads (43%) | called by muse, mutect2, varscan2
- P2RY13 | c.511T>C p.L171= | Silent (SNP) | VAF 113/278 reads (41%) | called by muse, mutect2, varscan2
- PCARE | c.2256C>T p.D752= | Silent (SNP) | VAF 141/196 reads (72%) | catalogued as rs375644198; called by muse, mutect2, varscan2
- PLA2R1 | c.175C>T p.L59= | Silent (SNP) | VAF 90/158 reads (57%) | catalogued as rs1165211630; called by muse, mutect2, varscan2
- PNPLA5 | c.1155C>T p.L385= | Silent (SNP) | VAF 48/259 reads (19%) | catalogued as rs770203375; called by muse, mutect2, varscan2
- RIMS2 | c.3798C>T p.R1266= | Silent (SNP) | VAF 56/167 reads (34%) | catalogued as rs1287561799; called by muse, mutect2, varscan2
- RYR2 | c.12084G>A p.S4028= | Silent (SNP) | VAF 81/181 reads (45%) | catalogued as rs751821960, COSV63682739, COSV63702754; ClinVar: likely benign; called by muse, mutect2, varscan2
- SAMD9L | c.453G>A p.K151= | Silent (SNP) | VAF 26/176 reads (15%) | called by muse, mutect2, varscan2
- SEL1L3 | c.468C>T p.Y156= | Silent (SNP) | VAF 63/139 reads (45%) | called by muse, mutect2, varscan2
- SLC17A9 | c.1101C>T p.C367= | Silent (SNP) | VAF 90/254 reads (35%) | catalogued as rs778254246; called by muse, mutect2, varscan2
- SLC5A2 | c.1152G>A p.A384= | Silent (SNP) | VAF 154/578 reads (27%) | catalogued as CD035009, COSV57891854; called by muse, mutect2, varscan2
- SPHK2 | c.1548C>T p.P516= | Silent (SNP) | VAF 49/136 reads (36%) | catalogued as rs1451837747, COSV55335124; called by muse, mutect2, varscan2
- SRPK3 | c.465C>T p.V155= | Silent (SNP) | VAF 43/190 reads (23%) | called by muse, mutect2, varscan2
- STIP1 | c.42C>T p.A14= | Silent (SNP) | VAF 56/329 reads (17%) | catalogued as rs777596225; called by muse, mutect2, varscan2
- TEP1 | c.1290G>T p.V430= | Silent (SNP) | VAF 9/153 reads (6%) | called by muse, mutect2
- TEX22 | c.300C>G p.A100= | Silent (SNP) | VAF 99/243 reads (41%) | called by muse, mutect2, varscan2
- TMTC1 | c.570C>A p.G190= (on ENST00000539277 / NM_001193451.2; = p.G82= on NM_175861.3) | Silent (SNP) | VAF 72/201 reads (36%) | called by muse, mutect2, varscan2
- TNR | c.3234C>T p.T1078= | Silent (SNP) | VAF 65/172 reads (38%) | catalogued as rs200777712, COSV54902159; called by muse, mutect2, varscan2
- VPS53 | c.1002C>T p.T334= (on ENST00000571805 / NM_001366253.2; = p.T305= on NM_018289.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/47 reads (55%) | called by muse, mutect2, varscan2
- ZAP70 | c.60C>T p.A20= | Silent (SNP) | VAF 105/291 reads (36%) | catalogued as rs1204892323; called by muse, mutect2, varscan2
- ZBTB10 | c.588C>A p.G196= | Silent (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- ZNF717 | c.267G>C p.L89= | Silent (SNP) | VAF 28/169 reads (17%) | called by muse, mutect2, varscan2
- AC004080.3 | c.11-4490C>T | Intron (SNP) | VAF 294/955 reads (31%) | called by muse, varscan2
- AC244517.10 | c.36-8591G>A | Intron (SNP) | VAF 56/170 reads (33%) | catalogued as rs781803344, COSV101595483; called by muse, mutect2
- CCSER1 | c.2095-12094A>G | Intron (SNP) | VAF 28/105 reads (27%) | called by muse, mutect2, varscan2
- COL3A1 | c.*28A>T | 3'UTR (SNP) | VAF 13/130 reads (10%) | called by muse, mutect2
- DNAJA4 | chr15:78264257 C>T | 5'Flank (SNP) | VAF 50/51 reads (98%) | catalogued as rs1315129556; called by muse, mutect2, varscan2
- FAM149A | c.1602+301C>T | Intron (SNP) | VAF 65/153 reads (42%) | catalogued as rs563612662; called by muse, mutect2, varscan2
- FXR1 | c.51+2770G>T | Intron (SNP) | VAF 14/90 reads (16%) | called by muse, varscan2
- KDM5A | c.1653+57T>C | Intron (SNP) | VAF 32/336 reads (10%) | called by muse, mutect2
- MRPL10 | c.52+40C>T | Intron (SNP) | VAF 86/326 reads (26%) | catalogued as rs1367693303; called by muse, mutect2, varscan2
- MTR | c.-180G>T | 5'UTR (SNP) | VAF 60/257 reads (23%) | called by muse, mutect2, varscan2
- NEUROD1 | c.-6C>T | 5'UTR (SNP) | VAF 54/169 reads (32%) | called by muse, mutect2, varscan2
- NFATC2 | c.*110C>T | 3'UTR (SNP) | VAF 300/423 reads (71%) | catalogued as rs542710098, COSV65360154; called by muse, mutect2, varscan2
- RFNG | c.829-116C>T | Intron (SNP) | VAF 22/97 reads (23%) | catalogued as rs776548580; called by muse, mutect2, varscan2
- RNF170 | c.*483A>T | 3'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- SEPTIN9 | c.*495G>A | 3'UTR (SNP) | VAF 82/263 reads (31%) | catalogued as rs773245212; called by muse, mutect2, varscan2
- SNORD114-1 | n.72A>C | RNA (SNP) | VAF 41/41 reads (100%) | called by muse, mutect2, varscan2
- SSPOP | n.6964G>A | RNA (SNP) | VAF 167/490 reads (34%) | catalogued as rs569350279, COSV50487248; called by muse, mutect2, varscan2
- STAT1 | c.-1-376A>T | Intron (SNP) | VAF 34/107 reads (32%) | called by muse, mutect2, varscan2
- TP73-AS1 | n.1549G>A | RNA (SNP) | VAF 148/276 reads (54%) | catalogued as rs562084723; called by muse, mutect2, varscan2
- ZEB1 | c.58+44235T>G | Intron (SNP) | VAF 58/237 reads (24%) | called by muse, mutect2, varscan2
- ZNF625 | chr19:12142506 C>A | 3'Flank (SNP) | VAF 114/196 reads (58%) | called by muse, mutect2, varscan2
